MMRF case MMRF_2394 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a8b6b3f6-fd57-4aed-a1b6-a5165e8baa65

Demographics
Sex at birth: male; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,450 days); ISS stage: I; Days to last known disease status: 728 days (2.0 years); Days to last follow up: 728 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 582 days (1.6 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 440 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 582 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 2): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 238 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 4 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 33.6 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 8.8 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.827 mg/dL.
- Day 89 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 2.27 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.3 g/dL; Glucose 4.35 mmol/L.
- Day 173 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 1.92 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 4.9 g/dL; Glucose 4.9 mmol/L.
- Day 259 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 1.97 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.1 g/dL; Glucose 3.52 mmol/L.
- Day 376 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 2.57 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.2 g/dL; Glucose 6.22 mmol/L.
- Day 454: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 58.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 5.06 mmol/L.
- Day 514: M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 2.22 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 4.84 mmol/L.
- Day 637: M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 1.93 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 5.06 mmol/L.
- Day 728: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 1.37 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 4.48 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.3 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -9: Weight: 71 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2394_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2394_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
